Gene-level copy-number profile of tumor specimen BLGSP-71-32-00698-01B from CGCI case BLGSP-71-32-00698, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 44.2 years (16,162 days).
Specimen BLGSP-71-32-00698-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d560eb5f-77e5-4876-b55b-ee881b2d6f69.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-32-00698-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/c8181247-54f3-46f0-b4b0-67404c982b46

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 268; copy number 1: 5,887; copy number 2: 46,426; copy number 3: 5,485; copy number 4: 316; copy number 5: 3; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 258 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,234,774–9,271,337, 1 gene: H6PD.
- chr1:47,688,463–47,704,029, 1 gene: LINC01738.
- chr1:47,761,132–47,820,237, 2 genes (within-gene range 0–2): AL691459.1, AC096541.1.
- chr2:120,866,378–120,867,403, 1 gene (within-gene range 0–2): AC017033.1.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr7:142,482,548–142,802,748, 56 genes: TRBV5-5, TRBV6-7, TRBV7-6, TRBV5-6, TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr8:22,578,279–22,604,150, 3 genes: PDLIM2, AC037459.1, C8orf58.
- chr9:64,462,819–64,489,786, 5 genes: CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6.
- chr10:100,987,367–101,061,005, 5 genes (within-gene range 0–2): TWNK, LZTS2, PDZD7, SFXN3, AL133215.2.
- chr14:21,941,128–22,552,156, 110 genes (within-gene range 0–2) (broad region; genes not listed).
- chr15:65,053,337–65,079,948, 2 genes (within-gene range 0–3): RASL12, KBTBD13.
- chr20:760,080–776,015, 1 gene: SLC52A3.
- chr22:22,380,766–22,896,111, 70 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:222,477,252–222,519,732, 3 genes, copy number 5: AL513314.2, RNU6-791P, AL592148.2.
- chr12:37,575,587–37,576,384, 1 gene, copy number 6: ZNF970P.

Autosomal genes at a single copy (total copy number 1): 3,553. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
